Gene-level copy-number profile of tumor specimen TCGA-DK-A2I6-01A from TCGA case TCGA-DK-A2I6, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 81.6 years (29,789 days).
Specimen TCGA-DK-A2I6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.c682e10e-87ab-4116-8e51-ad5a171982b8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A2I6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 820 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fa12d850-d2c9-4c71-b87c-d563402c66bf

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 77; copy number 2: 1,124; copy number 3: 11,475; copy number 4: 17,499; copy number 5: 9,395; copy number 6: 7,794; copy number 7: 4,939; copy number 8: 3,212; copy number 9: 1,122; copy number 10: 995; copy number 11: 356; copy number 12: 404; copy number 13: 335; copy number 14: 573; copy number 15: 16; copy number 16: 70; copy number 17: 40; copy number 18: 85; copy number 19: 83; copy number 20: 34; copy number 23: 29; copy number 25: 12; copy number 26: 75; copy number 29: 4; copy number 38: 53.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-A2I6-01A-12D-A18E-01): tumor purity 0.54, ploidy 5.13, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:71,215,618–71,237,158, 2 genes: AC091691.2, AC091691.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4,286 genes in 62 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:24,556,087–25,430,192, 26 genes, copy number 10 (within-gene range 8–10): NCMAP, Y_RNA, SRRM1, AL445648.1, CLIC4, RNU6-1208P, RUNX3, MIR6731, RUNX3-AS1, AL445471.1, MIR4425, LINC02793, AL050344.1, IFITM3P7, AL031432.1, SYF2, AL031432.4, AL031432.5, RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1, TMEM50A, RHCE.
- chr1:153,070,224–156,299,307, 197 genes, copy number 14 (broad region; genes not listed).
- chr1:157,691,762–158,267,320, 18 genes, copy number 9–18: AL356276.1, AL356276.2, VDAC1P9, FCRL2, FCRL1, CD5L, MRPS21P2, AL139010.1, KIRREL1, KIRREL1-IT1, SMIM42, LINC01704, ELL2P1, CD1D, AL138899.2, AL138899.1, CD1A, HMGN1P5.
- chr1:160,190,575–163,769,691, 128 genes, copy number 10–23 (broad region; genes not listed).
- chr1:227,696,892–231,566,524, 135 genes, copy number 9–16 (broad region; genes not listed).
- chr1:233,904,676–235,452,443, 50 genes, copy number 9 (within-gene range 4–9): SLC35F3, RAC1P7, AL122008.3, AL122008.1, SLC35F3-AS1, AL122008.2, MIR4671, AL355472.1, AL355472.2, AL355472.3, COA6-AS1, COA6, TARBP1, LINC01354, AL161640.2, AL161640.3, AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, AL160408.6, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3, LINC01348, AL732292.1, AL732292.2, TOMM20, SNORA14B, RBM34, ARID4B, MIR4753, RPL23AP23, GGPS1, AL357556.3, AL391994.1, AL357556.1, AL357556.5, TBCE, RPS21P1.
- chr2:5,313,740–10,785,110, 99 genes, copy number 9–13 (broad region; genes not listed).
- chr2:18,403,967–23,332,044, 69 genes, copy number 9 (broad region; genes not listed).
- chr2:65,310,851–67,825,562, 34 genes, copy number 10 (within-gene range 7–10): SPRED2, AC012370.1, AC007389.1, AC012370.2, DNAJB12P1, RPS15AP15, RN7SL635P, VTRNA2-2P, AC007389.2, AC007389.3, KRT18P33, AC007741.1, AC118345.1, AC092669.1, MIR4778, LINC01873, MEIS1-AS3, MEIS1, MEIS1-AS2, LINC01798, LINC01797, DNMT3AP1, AC009474.1, LINC01799, LINC01628, AC007403.1, LINC01828, LINC01829, AC023115.1, ETAA1, LINC02831, AC007422.1, AC010987.1, LINC01812.
- chr2:69,829,660–80,870,190, 219 genes, copy number 9–17 (within-gene range 8–17) (broad region; genes not listed).
- chr2:100,722,221–116,818,761, 323 genes, copy number 9–11 (broad region; genes not listed).
- chr3:11,745–36,548,007, 472 genes, copy number 10–20 (within-gene range 10–23) (broad region; genes not listed).
- chr3:59,050,164–68,953,297, 89 genes, copy number 9–13 (within-gene range 7–13) (broad region; genes not listed).
- chr3:70,605,420–75,339,071, 66 genes, copy number 9–14 (broad region; genes not listed).
- chr4:73,337,233–75,565,871, 50 genes, copy number 9: AC108157.1, ALB, AFP, AFM, LINC02499, AC074250.1, RASSF6, UMLILO, CXCL8, AC112518.1, CXCL6, PPBPP1, PF4V1, CXCL1, HNRNPA1P55, CXCL1P1, PF4, PPBP, CXCL5, AC097709.1, RN7SL218P, CXCL3, PPBPP2, AC093677.3, AC093677.1, CXCL2, MTHFD2L, AC093677.2, EPGN, EREG, AC021180.1, AREG, AC239584.1, BTC, AC098825.1, HSPE1P23, PARM1, PARM1-AS1, AC110760.1, LINC02562, AC110760.2, AC093870.1, AC025244.1, AC025244.2, LINC02483, AC096759.1, AC096759.2, RCHY1, THAP6, ODAPH.
- chr4:77,157,207–78,916,372, 27 genes, copy number 9 (within-gene range 7–9): CCNG2, AC008638.3, AC008638.2, AC008638.1, AC092674.1, CXCL13, AC104701.1, CNOT6L, MRPL1, AC112225.1, AC114801.2, HMGB1P44, HNRNPA1P56, AC114801.1, AC114801.3, FRAS1, SERBP1P5, MICOS10P4, ANXA3, Y_RNA, LINC01094, HIGD1AP13, AC112253.1, AC098818.1, AC098818.2, BMP2K, AC098818.3.
- chr4:92,303,966–94,370,163, 14 genes, copy number 10 (within-gene range 4–10): GRID2, MTND1P19, AC095059.2, AC095059.1, AC020699.1, AC110800.1, RNA5SP164, ATOH1, AC096746.1, HMGB3P15, SMARCAD1, HPGDS, AC109925.1, RPL35AP11.
- chr5:29,239,922–44,658,569, 256 genes, copy number 10–20 (within-gene range 8–20) (broad region; genes not listed).
- chr5:50,396,192–52,080,987, 25 genes, copy number 16: EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2, RNA5SP182, KATNBL1P4, AC091903.1, LINC02118.
- chr6:20,042,455–26,104,337, 111 genes, copy number 9 (broad region; genes not listed).
- chr6:29,212,886–30,742,732, 123 genes, copy number 10–14 (broad region; genes not listed).
- chr6:51,615,299–56,954,649, 89 genes, copy number 10–19 (within-gene range 6–19) (broad region; genes not listed).
- chr7:16,849,957–17,940,501, 15 genes, copy number 10 (within-gene range 7–10): AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1, SNX13.
- chr8:37,516,399–46,028,892, 167 genes, copy number 9–26 (broad region; genes not listed).
- chr8:62,110,524–65,843,331, 51 genes, copy number 9–10: NARS1P2, AC104852.1, AC023095.1, NKAIN3, AC018861.2, AC018861.1, AC090577.1, XRCC6P4, SRPK2P, AC120042.1, GGH, AC120042.2, TTPA, AC011978.1, YTHDF3-AS1, YTHDF3, AC011978.2, RN7SL135P, AC011124.1, IFITM8P, AC011124.2, AC018953.1, RN7SKP135, AC018953.2, LINC01414, AC069133.1, LINC01289, COX6CP8, MIR124-2HG, MIR124-2, AC012535.1, AC090136.1, AC090136.2, AC090136.3, BHLHE22, CYP7B1, AC104232.2, AC104232.3, AC104232.1, AC087808.1, RPL31P41, LINC00251, PPIAP86, LINC01299, AC100814.1, Y_RNA, ARMC1, MTFR1, AC055822.1, PDE7A, AC100812.1.
- chr8:94,097,764–101,452,452, 164 genes, copy number 10–19 (within-gene range 5–19) (broad region; genes not listed).
- chr8:102,923,371–104,256,094, 29 genes, copy number 13 (within-gene range 5–13): RPL5P24, Y_RNA, NPM1P52, AP003550.1, ATP6V1C1, MTND1P5, MTCO1P4, MTCO2P4, LINC01181, BAALC-AS2, BAALC, BAALC-AS1, MIR3151, AC025370.1, FZD6, AC025370.2, CTHRC1, AC012213.3, RNU6-1011P, SLC25A32, AC012213.5, DCAF13, AC012213.2, AC012213.4, AC012213.1, RIMS2, PTMAP15, AC007751.1, AC090686.1.
- chr8:106,980,967–112,148,825, 51 genes, copy number 9–19: AP003789.1, AP000428.2, HMGB1P46, AP000428.1, ANGPT1, AC091010.1, PGAM1P13, AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, U2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, AC022360.1, RNU4-37P.
- chr9:33,383,179–43,045,120, 344 genes, copy number 10–12 (broad region; genes not listed).
- chr12:51,391,317–52,059,507, 18 genes, copy number 12 (within-gene range 4–12): SLC4A8, AC107031.1, SCN8A, HNRNPA3P10, AC068987.1, TMDD1, AC068987.2, FIGNL2, AC068987.3, FIGNL2-DT, ANKRD33, AC025259.2, ACVRL1, ACVR1B, RNU6-574P, TAMALIN, NR4A1, NR4A1AS.
- chr13:48,653,711–49,793,307, 22 genes, copy number 38: CYSLTR2, PSME2P2, AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2, COX7CP1, OGFOD1P1, MLNR, AL137000.1, CDADC1, CAB39L, SETDB2, SNRPGP14, PHF11, RCBTB1, AL135901.1, ARL11, EBPL, KPNA3, AL136301.1.
- chr13:62,397,645–64,076,044, 17 genes, copy number 12–29 (within-gene range 4–29): AL356102.1, SQSTM1P1, AL445668.1, LINC00448, AL354810.1, LINC00376, AL359208.1, LINC00395, OR7E156P, AL445989.2, AL445989.1, RNU6-81P, PPP1R2P10, AL445238.2, OR7E104P, AL445238.1, LINC00355.
- chr13:66,977,432–69,408,735, 23 genes, copy number 11: PCDH9-AS3, PCDH9-AS4, AL160254.1, RPSAP53, LINC00364, AL512452.1, BCRP9, NPM1P22, OR7E111P, OR7E33P, AL590027.1, ELL2P3, HNRNPA1P18, RPL37P21, RPS3AP52, RPL12P34, RN7SL761P, LINC00550, LINC02342, ZDHHC20P4, SNRPFP3, LINC00383, SRSF1P1.
- chr17:37,375,985–40,284,136, 120 genes, copy number 11–38 (within-gene range 3–38) (broad region; genes not listed).
- chr17:62,910,021–70,368,916, 208 genes, copy number 10 (broad region; genes not listed).
- chr19:27,638,483–31,595,720, 79 genes, copy number 10–25 (broad region; genes not listed).
- chr19:37,545,470–38,975,742, 68 genes, copy number 26 (within-gene range 6–26) (broad region; genes not listed).
- chr19:42,821,863–43,596,135, 33 genes, copy number 9 (within-gene range 5–9): PSG8-AS1, PSG10P, PSG1, PSG6, PSG7, CEACAMP7, AC004784.1, PSG11, CEACAMP8, PSG2, CEACAMP9, AC005392.1, PSG5, PSG4, CEACAMP10, PSG9, CEACAMP11, CEACAMP4, AC005392.2, CD177, AC005392.3, CD177P1, TEX101, LYPD3, PHLDB3, ETHE1, ZNF575, XRCC1, L34079.2, L34079.1, L34079.3, PINLYP, IRGQ.
- chr20:17,693,672–20,360,703, 61 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr20:20,970,448–24,446,314, 93 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 77. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
